Surgical pathology report (de-identified scan), TCGA case TCGA-SC-A6LR, project TCGA-MESO (Mesothelioma), tissue source site Memorial Sloan Kettering, specimen TCGA-SC-A6LR-01A (Primary Tumor).

[page 1 of 6]
1CD-0-3

C9CF - Mesothelioma, diffuse epithelioid,
Malignant 9052/3

Path - Mesothelioma, epithelioid, malignant
9052/3

SURGICAL PATHOLOGY REPORT

Site: Pleura, (R) C38.4
NUS

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Sex: [REDACTED]
Account #: [REDACTED] Date of Procedure:
DOB: [REDACTED] (Age:) M Date of Receipt:
Physician: [REDACTED] Date of Report:
CC: [REDACTED]

hw 9/13/13

Clinical Diagnosis & History:
year old male with malignant mesothelioma epithelioid type.

Specimens Submitted:

- 1: Right pleura
- 2: Biopsy level eight mediastinal lymph node (fs)
- 3: Biopsy level seven mediastinal lymph node (fs)
- 4: Right level four mediastinal lymph node (fs)
- 5: Portion of right sixth rib
- 6: Level seven mediastinal lymph node
- 7: Right level four mediastinal lymph node
- 8: Level eight mediastinal lymph node

DIAGNOSIS:

1. Right pleura, biopsy:
- Malignant mesothelioma, epithelioid type
2. Biopsy level eight mediastinal lymph node, excision:
- Malignant mesothelioma, epithelioid type
- No lymphoid tissue identified
3. Biopsy level seven mediastinal lymph node, excision:
- One benign lymph node (0/1) with non-necrotizing granuloma, see note
4. Right level four mediastinal lymph node, excision:
- Fragments of one benign lymph node(s) with non-necrotizing granuloma
5. Portion of right sixth rib, excision:
- Benign bone and cellular marrow with focal marrow fibrosis, see note.
6. Level seven mediastinal lymph node, excision:
- Metastatic malignant mesothelioma to one lymph node fragment
- Non-necrotizing granuloma
7. Right level four mediastinal lymph node, excision:
- Fragments of one benign lymph node(s) with non-necrotizing granuloma
8. Level eight mediastinal lymph node, excision:
- Malignant mesothelioma, epithelioid type, see note
- No lymphoid tissue identified

** Continued on next page **

[page 2 of 6]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account #: [REDACTED]

Accession #: [REDACTED]

Physician: [REDACTED]

Service: [REDACTED]

Date of Report: [REDACTED]

Page 2 of 6

Note: The tumor cells are positive for calretinin, WT1, D2-40, AE1/3, CD15, but negative for TTF1 and pCEA. Despite the positivity of CD15, the morphology and the remaining staining pattern are consistent with malignant mesothelioma.

In parts 3, 4, 6, and 7, non-necrotizing granulomas are present. GMS and FITE stains are performed in part 3. No fungi or mycobacteria are seen on GMS and FITE stains.

In part 5, focal fibrosis is present in the bone marrow. Immunostain for cKit highlights the scattered mast cells. Immunostain for S100 is negative. The fibrotic area shows increased fibrosis by reticulin stain (1+), but negative Giemsa staining. The selected slides (block 5-2, HE, immuno and special stain) have been reviewed by [REDACTED] who concurs.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
	GMS	
	FITE	
	GMS	
	FITE	
	GIEMSA	
	RBTIC	
	RHCUT	

Gross Description:

1). The specimen is received fresh labeled "Right pleura." It consists of multiple fragmented pieces of membranous, rubbery, brown-tan soft tissue measuring 5.0 x 4.0 x 1.5 cm in aggregate. Representative sections are submitted.

Summary of sections:

U - undesignated

2). The specimen is received frozen section consultation labeled "biopsy level 8 mediastinal lymph node" and consists of two pink to tan soft tissue fragments measuring 1.5 x 1.5 x 0.4 cm in aggregate, which are entirely submitted in frozen section consultation.

** Continued on next page **

[page 3 of 6]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account #: [REDACTED]

Accession #: [REDACTED]

Physician: [REDACTED]

Service: [REDACTED]

Date of Report: [REDACTED]

Page 3 of 6

Summary sections:
FSC-frozen section control

3). The specimen is received fresh for frozen section consultation labeled "biopsy level 7 mediastinal lymph node" and consists of a fatty fibrous tissue measuring 5.0 x 1.5 x 0.6 cm to include a fatty possible lymph node. The lymph node is serially sectioned and entirely submitted for frozen section consultation.

Summary sections:
FSCA-frozen section control
FSCB-frozen section control

4) The specimen is received fresh for intraoperative consultation, labeled "right level 4 mediastinal lymph node", and consists of multiple anthracotic lymph nodes and adipose tissue measuring 3.3 x 1.8 x 0.4 cm in aggregate. The specimen is entirely submitted.

Summary of sections:
FSC - lymph node
U - undesignated

5) The specimen is received in formalin, labeled "portion of right sixth rib" and consists of multiple shaved segments of rib measuring 3.1 x 1.4 x 0.3 up to 11.8 x 1.2 x 0.4 cm. Red, tan soft tissue is attached. The cut surfaces reveal a homogenous red tan granular and bony cut surface. The cortical surface appears intact, and no discrete lesions are noted. Representative sections are submitted for decalcification.

Summary of sections:
U -- Undesignated

6) The specimen is received in formalin, labeled "level 7 mediastinal lymph node", and consists of multiple anthracotic lymph nodes measuring 1.6 x 1.6 x 0.8 cm in aggregate. The specimen is entirely submitted.

Summary of sections:
U - undesignated

** Continued on next page **

[page 4 of 6]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account #: [REDACTED]

Accession #: [REDACTED]

Physician: [REDACTED]

Service: [REDACTED]

Date of Report: [REDACTED]

Page 4 of 6

7) The specimen is received in formalin, labeled "right level 4 mediastinal lymph node", and consists of multiple anthracotic lymph nodes measuring 1.0 x 0.8 x 0.3 cm in aggregate. The specimen is entirely submitted.

Summary of sections:

U - undesignated

8) The specimen is received fresh and placed in formalin, labeled "level 8 mediastinal lymph node #2", and consists of multiple portions of white-tan rubbery tissue measuring 1.8 x 1.5 x 0.4 cm in aggregate. TFS is not submitted. The specimen is entirely submitted.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: Right pleura

Block	Sect.	Site	PCs
2		u	2

Part 2: Biopsy level eight mediastinal lymph node (fs)

Block	Sect.	Site	PCs
1		FSC	1

Part 3: Biopsy level seven mediastinal lymph node (fs)

Block	Sect.	Site	PCs
1		FGCA	1
1		FSCB	1

Part 4: Right level four mediastinal lymph node (fs)

Block	Sect.	Site	PCs
1		fsc	1
3		U	3

Part 5: Portion of right sixth rib

Block	Sect.	Site	PCs
2		U	2

Part 6: Level seven mediastinal lymph node

Block	Sect.	Site	PCs
2		U	2

** Continued on next page **

[page 5 of 6]
SURGICAL PATHOLOGY REPORT
Patient: [REDACTED]
MRN: [REDACTED]
Account #: [REDACTED]

Accession #: [REDACTED]
Physician: [REDACTED]
Service: [REDACTED]
Date of Report: [REDACTED]

Page 5 of 6

Part 7: Right level four mediastinal lymph node

Block	Sect. Site	PCs
1	U	1

Part 8: Level eight mediastinal lymph node

Block	Sect. Site	PCs
2	U	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- [REDACTED]
2. FROZEN SECTION DIAGNOSIS: Biopsy level eight mediastinal lymph node (fs): Malignant epithelioid neoplasm.
PERMANENT DIAGNOSIS: same
3. FROZEN SECTION DIAGNOSIS: Biopsy level seven mediastinal lymph node (fs): Benign.
PERMANENT DIAGNOSIS: same
4. FROZEN SECTION DIAGNOSIS: Right level four mediastinal lymph node (fs): Benign.
PERMANENT DIAGNOSIS: same

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- [REDACTED]
2. FROZEN SECTION DIAGNOSIS: Biopsy level eight mediastinal lymph node (fs): Malignant epithelioid neoplasm.
PERMANENT DIAGNOSIS: same
3. FROZEN SECTION DIAGNOSIS: Biopsy level seven mediastinal lymph node (fs): Benign.
PERMANENT DIAGNOSIS: same
4. FROZEN SECTION DIAGNOSIS: Right level four mediastinal lymph node (fs): Benign.
PERMANENT DIAGNOSIS: same

** Continued on next page **

[page 6 of 6]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

MRN: [REDACTED]

Account #: [REDACTED]

Accession #: [REDACTED]

Physician: [REDACTED]

Service: [REDACTED]

Date of Report: [REDACTED]

Page 6 of 6

**** End of Report ****

Source: NCI Genomic Data Commons file 9cfcb85b-f85a-452a-ac68-9f933059d117 (TCGA-SC-A6LR.E1F77E03-1351-48F3-9AE8-906F910F8883.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).